Gene-level copy-number profile of tumor specimen ALCH-B3F5-TTP1-A from ALCHEMIST case ALCH-B3F5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 72.8 years (26,578 days).
Specimen ALCH-B3F5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 94dd113f-c14d-4034-87f4-2216f599249a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3F5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/369fdabc-cc39-45e7-be33-9b20f59a89ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 18,216; copy number 2: 35,483; copy number 3: 3,640; copy number 4: 800; copy number 5: 623; copy number 15: 72.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:135,052,292–135,531,218, 4 genes (within-gene range 0–2): RAB3GAP1, SNORA40B, ZRANB3, G3BP1P1.
- chr2:217,900,513–217,900,628, 1 gene (within-gene range 0–1): MIR6809.
- chr3:75,384,059–75,538,029, 7 genes (within-gene range 0–4): AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2.
- chr5:134,967,907–135,034,813, 2 genes (within-gene range 0–1): CATSPER3, PITX1.
- chr5:135,034,521–135,040,047, 2 genes (within-gene range 0–1): AC008406.3, C5orf66-AS1.
- chr9:64,765,054–64,765,535, 1 gene: IGKV1OR-2.
- chr9:65,282,101–65,285,209, 1 gene: FOXD4L5.
- chr15:77,525,540–77,608,888, 2 genes: AC046168.1, AC046168.2.
- chr15:90,839,641–90,853,608, 1 gene: AC124248.1.
- chr17:142,789–386,254, 7 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3.
- chr21:45,263,928–45,573,365, 14 genes: POFUT2, LINC00205, BX322557.2, LINC00315, BX322557.1, LINC00316, MTCO1P3, BX322559.1, BX322562.1, COL18A1, COL18A1-AS2, COL18A1-AS1, MIR6815, SLC19A1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 695 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:197,311,393–197,516,737, 8 genes, copy number 5 (within-gene range 3–5): AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1.
- chr3:167,864,773–198,123,232, 591 genes, copy number 5 (broad region; genes not listed).
- chr7:140,084,746–140,176,983, 1 gene, copy number 5 (within-gene range 2–5): KDM7A.
- chr7:140,177,184–140,404,433, 8 genes, copy number 5 (within-gene range 2–5): KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248.
- chr9:35,406,755–37,592,604, 85 genes, copy number 5–15 (within-gene range 3–15) (broad region; genes not listed).
- chr9:37,650,954–37,746,904, 2 genes, copy number 5 (within-gene range 3–5): FRMPD1, RN7SKP171.

Autosomal genes at a single copy (total copy number 1): 15,405. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
